Surgical pathology report (de-identified scan), TCGA case TCGA-G9-A9S4, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-A9S4-01A (Primary Tumor).

[page 1 of 3]
Surg Date

SPECIMENS:

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

DIAGNOSIS:

- A. LYMPH NODES, RIGHT PELVIC, EXCISION:
- ONE OF FIVE LYMPH NODES IS POSITIVE FOR METASTATIC CARCINOMA (1/5)
- B. LYMPH NODES, LEFT PELVIC, EXCISION:
- THREE OF FIVE LYMPH NODES ARE POSITIVE FOR METASTATIC CARCINOMA (3/5)
- C. PROSTATE, PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 4+4=8/10, WITH TERTIARY COMPONENT OF 5, INVOLVING BOTH LEFT AND RIGHT LOBES, APPROXIMATELY 25% OF EXAMINED PROSTATIC TISSUE
- PERINEURAL INVASION IS IDENTIFIED
- ANGIOLYMPHATIC INVASION IS IDENTIFIED
- EXTRAPROSTATIC EXTENSION IS IDENTIFIED
- SEMINAL VESICLES AND VAS DEFERENS ARE INVOLVED BY CARCINOMA
- CARCINOMA CELLS ARE FOCALLY PRESENT AT THE LEVEL 3 LEFT POSTERIOR RESECTION MARGIN (THE ACCUMULATED LINEAR LENGTH IS APPROXIMATELY 1 MM)
- OTHER SURGICAL MARGINS ARE NEGATIVE FOR CARCINOMA
- SEE SYNOPTIC REPORT

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: RIGHT PELVIC LYMPH NODES
B: LEFT PELVIC LYMPH NODES
C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 25%

Gleason Grade/Sum:: Grade 4 + 4 , Sum 8 /10; Tertiary grade 5

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: Yes

Seminal Vesicle Invasion: Yes

Left

Right

Muscular Wall Invasion: Yes

Lumen Invasion: No

Periprostatic Fat Involved: Yes

Details: Bilateral posterior and base

Bladder Neck Involved: No

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

W 3/10/14

[page 2 of 3]
Surg Date .

Margins Involvement: Yes
Location: Left posterior (slide C21)
Linear Distance: Microscopic (<1mm)
Frozen Performed: No
Lymph Nodes: Positive Right 1 / 5 Left 3 / 5
Other Pathologic Findings: Chronic inflammation
Pathological Staging (pTNM): p T 3b N 1 M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:**A. RIGHT PELVIC LYMPH NODES**

Received in formalin labeled with the patient's identification and "right pelvic lymph node" are pieces of yellow-tan soft tissue in aggregate, 5.2 x 2.9 x 1.1 cm containing lymph nodes ranging from 0.7 x 0.6 x 0.3 cm to 2.5 x 1.7 x 0.7 cm. The largest lymph node is bisected; submitted entirely:

A1: 4 lymph nodes

A2: 1 bisected lymph node

A3: remainder of soft tissue

B. LEFT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and "left pelvic lymph node" are pieces of yellow-tan soft tissue in aggregate, 3.7 x 3.2 x 1.2 cm containing lymph nodes ranging from 0.4 x 0.3 x 0.2 cm to 3.4 x 1.1 x 0.7 cm. The larger lymph nodes are sectioned; submitted entirely:

B1: 4 lymph nodes

B2-B3: 1 lymph node in each cassette

B4: remainder of soft tissue

C. PROSTATE

Received in formalin, previously sectioned and procured, is a 49 g resected prostate gland measuring 4.7 cm from right lateral to left lateral, 4.5 cm from anterior to posterior, and 3.9 cm from apex to base. Ink code: Anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, posterior-black. After sectioning, the prostate has a nodular tan parenchyma.

The right seminal vesicle is 3 x 1.6 x 0.9 cm and the left is 3 x 1.6 x 1.1 cm; they consist of cystic tan tissue. The right vas deferens is 2.5 x 0.9 x 0.7 cm and the left is 2.8 x 1 x 0.7 cm; they consist of tubular tan tissue. Tissue is procured (6 g); submitted entirely:

C1-C2: perpendicular sections of the right apex

C3-C4: perpendicular sections of left apex

C5: level 1, right anterior

C6: level 1, right posterior

C7: level 1, left anterior

C8: level 1, left posterior

C9: level 2, right lateral capsule

C10: level 2, posterior capsule

C11: level 2, left lateral capsule

C12: level 2, anterior capsule

C13-C14: level 3, right anterior

C15-C17: level 3, right posterior

C18-C19: level 3, left anterior

C20-C22: level 3, left posterior

C23: perpendicular sections of right mid base

C24: perpendicular sections of left mid base

C25-C27: perpendicular sections of right lateral base

C28-C30: perpendicular sections of left lateral base

C31: perpendicular sections of right posterior base

C32: perpendicular sections of left posterior base

C33: perpendicular sections of right mid base urethral orifice margin

C34: perpendicular sections of left mid base urethral orifice margin

C35: right seminal vesicle and vas deferens

C36: left seminal vesicle and vas deferens

CLINICAL HISTORY:

None Given

[page 3 of 3]
Surg Date

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Gross Dictation:

Microscopic/Diagnostic Dictation: M.D., Pathologist,

Final Review: M.D., Pathologist,

Final: M.D., Pathologist,

Source: NCI Genomic Data Commons file a460e84a-daeb-43cf-82f8-05074f7d58a7 (TCGA-G9-A9S4.0507DFC9-971C-46F3-BC03-AACA10A49202.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).